Somatic mutation profile of tumor specimen 0DA690 from CCDI case PBBJUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.4 years (9,261 days).
Specimen 0DA690: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16a910a0-b815-4722-be93-71a0336ad2e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA691 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a527b7ec-899e-4159-bc0e-73f591f56b34

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1356_1358del p.N453del (on ENST00000521381 / NM_181523.3; = p.N183del on NM_181504.4) | In Frame Del (DEL) | VAF 148/504 reads (29%) | hotspot (GDC flag); called by mutect2, varscan2
- FGFR1 | c.1681G>A p.V561M (on ENST00000447712 / NM_023110.3; = p.V559M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/517 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58333193; called by muse, mutect2, varscan2
- ARMCX4 | c.600A>G p.I200M (on ENST00000433011; = p.I96M on NM_001256155.2) | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- KCNA7 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- MUC5AC | c.4303C>T p.P1435S | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYOCD | c.2628T>A p.N876K | Missense Mutation (SNP) | VAF 171/514 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PLXNB2 | c.879A>G p.L293= | Silent (SNP) | VAF 99/286 reads (35%) | catalogued as rs1410759013; called by muse, mutect2, varscan2
- TAF5L | c.1533C>T p.D511= | Silent (SNP) | VAF 20/582 reads (3%) | called by muse, mutect2
- MS4A4A | c.*22C>A | 3'UTR (SNP) | VAF 76/222 reads (34%) | catalogued as rs1224407631; called by muse, mutect2, varscan2
- SLC4A1 | c.-29G>A | 5'UTR (SNP) | VAF 145/454 reads (32%) | catalogued as rs201265907; called by muse, mutect2, varscan2
